Somatic mutation profile of tumor specimen 0DS4ME from CCDI case PBCHFU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.7 years (4,626 days).
Specimen 0DS4ME: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37520857-2c9d-4830-a723-ad7e4737cc44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS4MK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70f06f38-dc03-409c-bb0f-f32f602ed407

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Frame Shift Ins 3, 3'UTR 2, Nonsense Mutation 2, Translation Start Site 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 269/556 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 216/594 reads (36%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCG2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 276/616 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774024199; called by muse, mutect2, varscan2
- ACKR2 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 245/512 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99825515; called by muse, mutect2, varscan2
- BCL11A | c.832G>A p.A278T (on ENST00000335712 / NM_001365609.1; = p.A312T on NM_018014.4) | Missense Mutation (SNP) | VAF 273/582 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.29); catalogued as COSV100184971; called by muse, mutect2, varscan2
- C3orf56 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 248/533 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs764968388, COSV101228931; called by muse, mutect2, varscan2
- CBR3 | c.249dup p.L84Afs*15 | Frame Shift Ins (INS) | VAF 305/758 reads (40%) | catalogued as rs745795206; called by mutect2, pindel, varscan2
- DLGAP1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 242/485 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1440204317, COSV59829406; called by muse, mutect2, varscan2
- DYRK1B | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 169/350 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs757189339, COSV59914156; called by muse, mutect2, varscan2
- FREM3 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 33/640 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs532088660; called by muse, mutect2
- IKZF5 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 302/647 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs775039198, COSV64397443; called by muse, mutect2, varscan2
- MUC17 | c.3241T>C p.S1081P | Missense Mutation (SNP) | VAF 425/1018 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV60284137; called by muse, mutect2, varscan2
- OR8D2 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62489207; called by muse, mutect2
- PIK3CA | c.2237A>T p.D746V | Missense Mutation (SNP) | VAF 286/574 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV56014953; called by muse, mutect2, varscan2
- PTEN | c.170T>A p.L57* | Nonsense Mutation (SNP) | VAF 228/511 reads (45%) | catalogued as rs786202398, CD132273, COSV64291202, COSV64296794, COSV64310457; called by muse, mutect2, varscan2
- RNFT2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 35/921 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as rs1049184080, COSV57485428; called by muse, mutect2
- RPL22 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 271/582 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52377337, COSV52377608; called by muse, mutect2, varscan2
- SLIT2 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 267/556 reads (48%) | catalogued as COSV56600881; called by muse, mutect2, varscan2
- TRAF1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 275/603 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs36084135; called by muse, mutect2, varscan2
- TXNDC2 | c.377C>T p.T126I (on ENST00000306084 / NM_001098529.2; = p.T59I on NM_032243.6) | Missense Mutation (SNP) | VAF 54/1046 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as rs779157776; called by muse, mutect2
- USP35 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 208/498 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.1); catalogued as rs1373046304; called by muse, mutect2, varscan2
- DGKZ | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DOCK10 | c.4057C>A p.L1353M | Missense Mutation (SNP) | VAF 193/419 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FSCN3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 313/684 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HOXD13 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 338/745 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO3B | c.3281T>C p.I1094T | Missense Mutation (SNP) | VAF 175/380 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- NEUROD2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 303/694 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PITRM1 | c.796T>C p.F266L | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2
- RGPD3 | c.1390C>A p.H464N | Missense Mutation (SNP) | VAF 188/792 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ST18 | c.1862dup p.N621Kfs*14 | Frame Shift Ins (INS) | VAF 310/708 reads (44%) | called by mutect2, varscan2
- DYRK1B | c.1299C>T p.R433= | Silent (SNP) | VAF 171/351 reads (49%) | called by muse, mutect2, varscan2
- GPR20 | c.384C>T p.L128= | Silent (SNP) | VAF 236/513 reads (46%) | catalogued as rs1158981623; called by muse, mutect2, varscan2
- MAN2B1 | c.1023G>A p.A341= | Silent (SNP) | VAF 106/305 reads (35%) | catalogued as rs755616565, COSV55476012; ClinVar: likely benign; called by muse, mutect2
- MCMDC2 | c.1338T>A p.I446= | Silent (SNP) | VAF 220/508 reads (43%) | called by muse, mutect2, varscan2
- MUC5B | c.8466C>T p.P2822= | Silent (SNP) | VAF 641/1505 reads (43%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.1059C>G p.T353= | Silent (SNP) | VAF 112/307 reads (36%) | called by muse, mutect2, varscan2
- TLN2 | c.1401C>T p.N467= | Silent (SNP) | VAF 270/543 reads (50%) | catalogued as rs773713515, COSV60897581; called by muse, mutect2, varscan2
- AUP1 | c.671+60T>C | Intron (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- COL9A2 | c.*37C>T | 3'UTR (SNP) | VAF 124/242 reads (51%) | catalogued as rs774289715; called by muse, mutect2, varscan2
- LYVE1 | c.*93A>G | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- POLG | c.-27C>T | 5'UTR (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
